Somatic mutation profile of tumor specimen BA2344D (aliquot aq-BA2344D) from BEATAML1.0 case 2077, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.5 years (26,123 days).
Specimen BA2344D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a693eaf1-bcd4-4b70-aaa5-944770a55fa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2131D (Solid Tissue Normal), aliquot aq-BA2131D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc2c8135-3437-4f16-abb4-8ce415f6ef42

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, RNA 2, Intron 2, 5'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1D | c.3762G>C p.L1254F (on ENST00000350061 / NM_001128840.3; = p.L1274F on NM_000720.4) | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV55440602; called by muse, mutect2, varscan2
- CERS3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52569670; called by muse, mutect2, varscan2
- CHIA | c.383G>A p.R128H (on ENST00000343320; = p.R20H on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs140031055; called by muse, mutect2, varscan2
- JRK | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1048716496; called by muse, mutect2, varscan2
- KCNMA1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1465957812; called by muse, varscan2
- MMRN2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100922469, COSV64401397; called by muse, mutect2, varscan2
- PIGS | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52023858; called by muse, mutect2, varscan2
- PRAG1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs769325354, COSV58162654; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- SLC30A2 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as rs144832711; called by muse, mutect2, varscan2
- WT1 | c.1330_1331insAGGCCTAGGCCCCCA p.C444delins* | Nonsense Mutation (INS) | VAF 91/258 reads (35%) | catalogued as COSV99070074; called by mutect2, pindel, varscan2
- WT1 | c.1102_1103insA p.R368Qfs*5 | Frame Shift Ins (INS) | VAF 110/215 reads (51%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, pindel*
- CD109 | c.2384_2387del p.T795Kfs*4 | Frame Shift Del (DEL) | VAF 51/104 reads (49%) | called by mutect2, pindel*, varscan2
- CLPX | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- EFNB1 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRM3 | c.1061T>A p.F354Y | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HEPH | c.2368A>C p.T790P (on ENST00000343002; = p.T523P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KAT2A | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MARCHF11 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NLRP1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NRXN1 | c.1019T>G p.V340G | Missense Mutation (SNP) | VAF 152/444 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NUP188 | c.2093C>A p.T698N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUP98 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR14 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- TMEM94 | c.1131A>G p.E377= | Splice Region (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CNOT1 | c.117C>T p.H39= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs990801496; called by muse, mutect2
- AHSA2P | n.1493del | RNA (DEL) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- AZU1 | c.594+18C>A | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- BX537318.2 | n.618_619insGGGG | RNA (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel*, varscan2
- LEMD2 | c.-4G>C | 5'UTR (SNP) | VAF 29/67 reads (43%) | catalogued as rs757864405; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4262C>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- POSTN | c.*24G>A | 3'UTR (SNP) | VAF 65/133 reads (49%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.-45G>T | 5'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
